Somatic mutation profile of tumor specimen ALCH-B0BR-TTP1-A (aliquot ALCH-B0BR-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0BR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,918 days).
Specimen ALCH-B0BR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b9b481f-e58e-40cf-a3ee-346e713cc504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0BR-NB1-A (Blood Derived Normal), aliquot ALCH-B0BR-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2edeb669-833b-4a77-9a66-e06ffec2b313

The open-access MAF lists 224 somatic variants for this specimen: 156 protein-altering or splice-affecting, 42 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 42, Nonsense Mutation 19, Intron 13, RNA 9, Frame Shift Del 5, 5'UTR 3, Splice Region 3, Splice Site 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1804G>T p.G602W | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM152044; called by muse, mutect2, varscan2
- AHNAK2 | c.13577A>T p.Q4526L | Missense Mutation (SNP) | VAF 117/515 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as rs1321240630; called by muse, mutect2, varscan2
- ARHGEF11 | c.3223G>C p.E1075Q | Missense Mutation (SNP) | VAF 129/1230 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV59355350; called by muse, mutect2, varscan2
- ASPSCR1 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV60729996; called by muse, mutect2, varscan2
- ASTN1 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 317/800 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56063894; called by muse, mutect2, varscan2
- CHAF1A | c.1503G>C p.Q501H | Missense Mutation (SNP) | VAF 61/1143 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.43); catalogued as rs748345918; called by muse, mutect2
- COL6A2 | c.2797C>A p.R933S | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.027); catalogued as COSV52428946; called by muse, mutect2, varscan2
- CRHR1 | c.530G>A p.R177Q (on ENST00000398285 / NM_001145146.2; = p.R148Q on NM_004382.5) | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs377037950; called by muse, mutect2, varscan2
- CTSW | c.621C>A p.S207R | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV100327430; called by muse, mutect2, varscan2
- CYP2E1 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs61644766; called by muse, mutect2, varscan2
- DNAH5 | c.5713C>T p.H1905Y | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1178864639; called by muse, mutect2, varscan2
- DNTT | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 150/691 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as rs752907059, COSV100960506, COSV64523040; called by muse, mutect2, varscan2
- DOCK2 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV56973691; called by muse, mutect2, varscan2
- FAT1 | c.3115G>T p.E1039* | Nonsense Mutation (SNP) | VAF 62/232 reads (27%) | catalogued as COSV71673607, COSV71675431; called by muse, mutect2, varscan2
- FKBPL | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 180/951 reads (19%) | catalogued as COSV100913600; called by muse, mutect2, varscan2
- FREM2 | c.6659G>T p.G2220V | Missense Mutation (SNP) | VAF 86/377 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54842546; called by muse, mutect2, varscan2
- FZD3 | c.1963A>G p.M655V | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1235120240; called by muse, mutect2, varscan2
- GBP1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 122/681 reads (18%) | catalogued as rs768793043, COSV65084515; called by muse, mutect2, varscan2
- GRIN2A | c.2614C>A p.H872N | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV58034662, COSV58050763; called by muse, varscan2
- GRIN2B | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 86/468 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV74205530; called by muse, mutect2, varscan2
- HSP90AB1 | c.561_563del p.E187del | In Frame Del (DEL) | VAF 54/340 reads (16%) | catalogued as rs1561898868; called by pindel, varscan2
- IDUA | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 107/486 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD113571, CM022026, CM950681; called by muse, mutect2, varscan2
- KEAP1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 49/130 reads (38%) | catalogued as COSV50269587; called by muse, mutect2, varscan2
- KIF17 | c.944C>A p.A315E | Missense Mutation (SNP) | VAF 181/706 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56116679; called by muse, mutect2, varscan2
- KNTC1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1432290963; called by muse, mutect2, varscan2
- LAMA4 | c.4227G>T p.L1409F (on ENST00000230538 / NM_001105206.3; = p.L1402F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs1457030369; called by muse, mutect2, varscan2
- MAP4K3 | c.1119G>A p.L373= | Splice Region (SNP) | VAF 24/84 reads (29%) | catalogued as rs1258339662, COSV99809918; called by mutect2, varscan2
- NALCN | c.2054C>A p.S685Y | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV51927624; called by muse, mutect2, varscan2
- NELL1 | c.1724G>T p.C575F | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54240543; called by muse, mutect2, varscan2
- NKD2 | c.423G>T p.R141S | Missense Mutation (SNP) | VAF 109/587 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1373890778; called by muse, mutect2, varscan2
- NRAS | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs753954415, COSV54752206; called by muse, mutect2, varscan2
- OBSCN | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV52808176; called by muse, mutect2, varscan2
- OR2M2 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs375213372; called by muse, mutect2, varscan2
- OR4Q3 | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59179956; called by muse, mutect2, varscan2
- OR8K1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV54402875; called by muse, mutect2
- PCDHB11 | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 107/931 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100697081; called by muse, mutect2, varscan2
- PDE4DIP | c.3826G>A p.G1276S | Missense Mutation (SNP) | VAF 152/468 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781941246; called by muse, mutect2, varscan2
- POLR3E | c.473-1G>A p.X158_splice | Splice Site (SNP) | VAF 111/475 reads (23%) | catalogued as rs200801205; called by muse, mutect2, varscan2
- REG3A | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs147363673, COSV59409489, COSV59412525; called by muse, mutect2, varscan2
- RNASEH1 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 121/506 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs1373613692; called by muse, mutect2, varscan2
- SALL1 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 315/1396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99174393; called by muse, mutect2, varscan2
- SATB2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53484706, COSV99612569, COSV99612749; called by muse, mutect2, varscan2
- SHANK1 | c.1021G>T p.G341* | Nonsense Mutation (SNP) | VAF 30/610 reads (5%) | catalogued as COSV53255676; called by muse, mutect2
- SLC25A19 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 204/844 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs750975664; called by muse, mutect2, varscan2
- SLC4A7 | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs988128803, COSV99840276; called by muse, mutect2, varscan2
- SPAG5 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58803680; called by muse, mutect2, varscan2
- SPRR2F | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 42/390 reads (11%) | PolyPhen possibly damaging (0.598); catalogued as COSV64207730; called by muse, varscan2
- TAF2 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV65417294; called by muse, mutect2, varscan2
- TRAF1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 95/501 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs377746528; called by muse, mutect2, varscan2
- USP3 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.083); catalogued as COSV51428758; called by muse, mutect2, varscan2
- VWA3B | c.567G>C p.W189C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68247784; called by muse, mutect2, varscan2
- ZNF479 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58636446; called by muse, mutect2, varscan2
- ZNF71 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV60149485; called by muse, mutect2, varscan2
- ZNF716 | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV101348679; called by muse, mutect2, varscan2
- ACE | c.3691+8C>G | Splice Region (SNP) | VAF 82/438 reads (19%) | called by muse, mutect2, varscan2
- ADGRA3 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ADGRG4 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ADGRG6 | c.1915T>G p.L639V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ALB | c.1694A>G p.K565R | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- APPBP2 | c.323T>A p.I108K | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ASCC2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AXIN2 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C16orf96 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C3 | c.4642C>T p.R1548* | Nonsense Mutation (SNP) | VAF 26/604 reads (4%) | called by muse, mutect2
- C5orf34 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- CBLIF | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 147/640 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CDH23 | c.7453G>T p.A2485S | Missense Mutation (SNP) | VAF 115/497 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CES4A | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CHL1 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2, varscan2
- CHRNA10 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CLCA4 | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CLEC10A | c.872G>T p.W291L (on ENST00000254868 / NM_182906.4; = p.W267L on NM_006344.4) | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP3 | c.2338C>A p.L780M | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CRYBB2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 193/907 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CTAGE6 | c.984A>T p.L328F | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CUBN | c.5513G>C p.G1838A | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DNAH10 | c.10472G>T p.S3491I (on ENST00000409039; = p.S3430I on NM_207437.3) | Missense Mutation (SNP) | VAF 122/551 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAH7 | c.5277G>T p.W1759C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG3 | c.2903C>A p.P968H | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELP5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 136/503 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FAF1 | c.1648C>A p.R550S | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FAM110D | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- FAM13A | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- FAT4 | c.4933G>T p.G1645C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBLN1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- FGD2 | c.912C>A p.Y304* | Nonsense Mutation (SNP) | VAF 113/310 reads (36%) | called by muse, mutect2, varscan2
- FRMD6 | c.1135A>T p.K379* (on ENST00000344768 / NM_001267046.2; = p.K371* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 124/572 reads (22%) | called by muse, mutect2, varscan2
- GOSR2 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPATCH4 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 66/862 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- GPR37 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2H2C | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HEATR6 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- HELZ2 | c.4798del p.A1600Pfs*370 (on ENST00000467148 / NM_001037335.2; = p.A1031Pfs*370 on NM_033405.3) | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- HK3 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 169/803 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IL7R | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 73/306 reads (24%) | called by muse, mutect2, varscan2
- IRF2 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KATNAL1 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNA2 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 75/395 reads (19%) | called by muse, mutect2, varscan2
- KDM4A | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2026 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- KLHL34 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- KPNA7 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KRT18 | c.498_500+1del p.X166_splice | Splice Site (DEL) | VAF 89/410 reads (22%) | called by mutect2, pindel*, varscan2*
- LAMA1 | c.8792G>T p.G2931V | Missense Mutation (SNP) | VAF 198/827 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- METTL2B | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 58/452 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, varscan2
- MUC5B | c.5444G>A p.R1815K | Missense Mutation (SNP) | VAF 154/629 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- MYPN | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NELL1 | c.2216C>A p.A739D | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, varscan2
- NRBF2 | c.375A>T p.K125N | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NRDE2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- NUP62 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 241/1373 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR1M1 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2H2 | c.369_379del p.V124Pfs*47 | Frame Shift Del (DEL) | VAF 63/253 reads (25%) | called by mutect2, pindel, varscan2
- OXR1 | c.626C>A p.A209E (on ENST00000442977 / NM_001198532.1; = p.A208E on NM_018002.3) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC1L | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2
- PAX9 | c.513_517del p.K172Afs*143 | Frame Shift Del (DEL) | VAF 32/209 reads (15%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 179/785 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB1 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PCLO | c.6845A>T p.E2282V | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDHA2 | c.612A>T p.E204D | Missense Mutation (SNP) | VAF 135/579 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PEBP4 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3CG | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLPPR4 | c.1813G>T p.G605C | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, varscan2
- PLPPR4 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 86/392 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, varscan2
- PML | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 127/503 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PSG7 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 286/758 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RBMXL3 | c.2173C>A p.P725T | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RTN3 | c.2432C>G p.T811S (on ENST00000377819 / NM_001265589.2; = p.T792S on NM_201428.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR3 | c.9199G>T p.E3067* (on ENST00000389232; = p.E3068* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 127/496 reads (26%) | called by muse, mutect2, varscan2
- SEC24D | c.1313A>T p.N438I | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SFTPB | c.890_891del p.S297* | Frame Shift Del (DEL) | VAF 191/1100 reads (17%) | called by pindel, varscan2
- SIGMAR1 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 196/954 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SLITRK1 | c.221del p.F74Sfs*35 | Frame Shift Del (DEL) | VAF 124/595 reads (21%) | called by mutect2, pindel, varscan2
- STAG3 | c.2891T>A p.F964Y | Missense Mutation (SNP) | VAF 116/460 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- STK26 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT11 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 56/1044 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2
- TAX1BP1 | c.1410A>C p.S470= | Splice Region (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- TCERG1L | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 139/652 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- TCHHL1 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 218/376 reads (58%) | called by muse, mutect2, varscan2
- TCN1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TNRC6B | c.4403G>T p.G1468V (on ENST00000454349 / NM_001162501.2; = p.G1358V on NM_015088.3) | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53TG5 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 46/818 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); called by muse, mutect2
- TRO | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TRPV4 | c.1493C>A p.P498Q | Missense Mutation (SNP) | VAF 154/555 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC7B | c.2403G>T p.W801C | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.12206A>C p.D4069A | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USH2A | c.1402A>G p.N468D | Missense Mutation (SNP) | VAF 78/466 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- USP36 | c.1100T>A p.L367H | Missense Mutation (SNP) | VAF 74/401 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UVRAG | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 108/511 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VTI1A | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 40/433 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZC2HC1C | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZFHX4 | c.7453A>T p.S2485C | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF28 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 57/314 reads (18%) | called by muse, mutect2, varscan2
- ZNF404 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZUP1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALG12 | c.636C>T p.H212= | Silent (SNP) | VAF 194/790 reads (25%) | catalogued as rs771034460; called by muse, mutect2, varscan2
- CARNS1 | c.1266C>T p.L422= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs770711185; called by muse, mutect2, varscan2
- COL5A1 | c.57G>A p.L19= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs761259908; called by muse, varscan2
- COL5A1 | c.1797G>A p.P599= | Silent (SNP) | VAF 98/1028 reads (10%) | catalogued as rs201463583; ClinVar: likely benign; called by muse, mutect2
- DDX59 | c.1752G>A p.Q584= | Silent (SNP) | VAF 55/319 reads (17%) | catalogued as rs904886878; called by muse, mutect2, varscan2
- DIP2B | c.1350A>T p.L450= | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- DNAI2 | c.1230C>T p.L410= | Silent (SNP) | VAF 226/862 reads (26%) | called by muse, mutect2, varscan2
- EGR4 | c.1455C>T p.C485= (on ENST00000545030; = p.C382= on NM_001965.4) | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- FHAD1 | c.2916G>C p.P972= | Silent (SNP) | VAF 91/506 reads (18%) | called by muse, mutect2, varscan2
- GPATCH4 | c.12G>T p.R4= | Silent (SNP) | VAF 49/531 reads (9%) | catalogued as rs376788135; called by muse, mutect2
- GUCY2D | c.2976C>T p.T992= | Silent (SNP) | VAF 120/616 reads (19%) | called by muse, mutect2, varscan2
- HDAC4 | c.1299G>T p.L433= | Silent (SNP) | VAF 168/849 reads (20%) | called by muse, mutect2, varscan2
- HSD3B2 | c.882C>T p.G294= | Silent (SNP) | VAF 66/311 reads (21%) | called by muse, mutect2, varscan2
- KMT2E | c.450T>C p.D150= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as rs779469744; called by muse, mutect2
- KRTAP7-1 | c.192G>T p.L64= | Silent (SNP) | VAF 92/359 reads (26%) | called by muse, mutect2
- LRP1B | c.2574C>A p.I858= | Silent (SNP) | VAF 74/291 reads (25%) | catalogued as COSV100796625; called by muse, mutect2, varscan2
- MATN1 | c.1149C>T p.F383= | Silent (SNP) | VAF 77/278 reads (28%) | catalogued as rs1293714840, COSV65651131; called by muse, mutect2, varscan2
- MCAM | c.1269C>A p.V423= | Silent (SNP) | VAF 101/377 reads (27%) | called by muse, mutect2, varscan2
- MYO15A | c.2805C>A p.P935= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- MYO18B | c.6693G>T p.R2231= | Silent (SNP) | VAF 157/755 reads (21%) | catalogued as COSV100123641; called by muse, mutect2, varscan2
- NBPF3 | c.1674G>C p.L558= | Silent (SNP) | VAF 52/361 reads (14%) | catalogued as rs758878457; called by muse, varscan2
- NEUROD4 | c.45C>A p.V15= | Silent (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- NOX4 | c.486G>A p.L162= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV99631893; called by muse, mutect2, varscan2
- NR2C2 | c.789G>A p.T263= (on ENST00000393102; = p.T282= on NM_003298.5) | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs529430729, COSV60146280; called by muse, mutect2, varscan2
- OR14A2 | c.225A>T p.P75= | Silent (SNP) | VAF 95/191 reads (50%) | called by muse, mutect2, varscan2
- PCDH8 | c.2235A>G p.Q745= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs367629151; called by muse, mutect2, varscan2
- PLPPR4 | c.1992C>T p.N664= | Silent (SNP) | VAF 75/324 reads (23%) | catalogued as rs751234557; called by muse, varscan2
- PPFIA2 | c.72C>A p.G24= | Silent (SNP) | VAF 70/290 reads (24%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2172G>A p.S724= | Silent (SNP) | VAF 81/213 reads (38%) | catalogued as rs782003534; called by muse, mutect2, varscan2
- RELN | c.3351G>T p.L1117= | Silent (SNP) | VAF 101/448 reads (23%) | catalogued as COSV59037689; called by muse, mutect2, varscan2
- RIPK4 | c.93C>T p.G31= | Silent (SNP) | VAF 179/464 reads (39%) | called by muse, varscan2
- SALL1 | c.2754C>T p.A918= | Silent (SNP) | VAF 127/632 reads (20%) | catalogued as rs766776831; called by muse, mutect2, varscan2
- SFTPB | c.651G>A p.R217= | Silent (SNP) | VAF 94/539 reads (17%) | called by muse, mutect2, varscan2
- SLC52A1 | c.39C>T p.H13= | Silent (SNP) | VAF 29/453 reads (6%) | catalogued as rs760268319; called by muse, mutect2
- SLC5A11 | c.1299C>T p.I433= | Silent (SNP) | VAF 86/422 reads (20%) | called by muse, mutect2, varscan2
- TAGLN3 | c.339G>C p.T113= | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- VENTX | c.738G>T p.R246= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2
- WDR7 | c.2175C>A p.G725= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- YIPF6 | c.597C>G p.S199= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- ZNF571 | c.1311T>C p.H437= | Silent (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- ZNF852 | c.1470T>C p.T490= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs999959551; called by muse, mutect2, varscan2
- ZPLD1 | c.192G>A p.S64= (on ENST00000466937 / NM_001329788.1; = p.S80= on NM_175056.2) | Silent (SNP) | VAF 38/460 reads (8%) | catalogued as rs757680849, COSV100083534; called by muse, mutect2
- AC011525.1 | n.1018G>C | RNA (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- AC079921.1 | n.269+50845G>A | Intron (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+557C>A | Intron (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- AGBL3 | c.311-6919A>G | Intron (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- AGGF1 | c.-350G>A | 5'UTR (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2
- ARMH4 | c.1831+15072G>T | Intron (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.2745A>C | RNA (SNP) | VAF 66/349 reads (19%) | called by muse, mutect2, varscan2
- EHF | c.-4+1157C>G | Intron (SNP) | VAF 34/123 reads (28%) | catalogued as rs1217888575; called by muse, mutect2, varscan2
- GALNT13 | c.1396-868G>C | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.2111C>A | RNA (SNP) | VAF 76/321 reads (24%) | called by muse, mutect2, varscan2
- LINC00552 | n.360G>A | RNA (SNP) | VAF 104/457 reads (23%) | catalogued as rs566524948; called by mutect2, varscan2
- MUC20P1 | n.378T>A | RNA (SNP) | VAF 154/906 reads (17%) | called by muse, varscan2
- NAMPTP1 | n.1294G>T | RNA (SNP) | VAF 110/500 reads (22%) | called by muse, mutect2, varscan2
- PBXIP1 | c.-5C>T | 5'UTR (SNP) | VAF 60/428 reads (14%) | catalogued as rs1005231080; called by muse, mutect2, varscan2
- PEG10 | c.*189C>G | 3'UTR (SNP) | VAF 101/514 reads (20%) | called by muse, mutect2, varscan2
- PRRT1 | c.20-166C>A | Intron (SNP) | VAF 119/615 reads (19%) | called by muse, mutect2, varscan2
- PSMD13 | c.-31G>A | 5'UTR (SNP) | VAF 66/346 reads (19%) | called by muse, mutect2, varscan2
- RECK | c.637+1626dup | Intron (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- RPL23AP87 | n.1496G>A | RNA (SNP) | VAF 130/667 reads (19%) | catalogued as rs778283596; called by muse, mutect2, varscan2
- STXBP2 | c.246+251_246+254del | Intron (DEL) | VAF 413/899 reads (46%) | catalogued as rs1446322120; called by mutect2, pindel, varscan2
- TMEM51 | c.-267+14656C>T | Intron (SNP) | VAF 105/508 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10303+1329C>T | Intron (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- XKR4 | c.806+60904C>A | Intron (SNP) | VAF 64/308 reads (21%) | called by muse, mutect2, varscan2
- ZNF137P | n.1373G>T | RNA (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- ZNF680 | c.254-3975C>A | Intron (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- ZNF849P | n.1352A>T | RNA (SNP) | VAF 35/281 reads (12%) | catalogued as rs1223810883; called by muse, mutect2, varscan2
